Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAN7, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAN7-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

DIAGNOSIS:

RADICAL CYSTECTOMY WITH STUDDER POUCH TO URETHRA:

RIGHT DISTAL URETER (A):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

APICAL URETHRAL MARGIN F/S (C):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- BENIGN URETHRAL MUCOSA

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

BLADDER, PROSTATE (D):

BLADDER:

INTRAOPERATIVE GROSS CONSULTATION:

- TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA WITH SARCOMATOID FEATURES, POORLY DIFFERENTIATED, GRADE 4/4, INFILTRATING THROUGH THE MUSCULARIS PROPRIA TO THE PERIVESICAL FAT, BUT NOT AT THE MARGINS
- LYMPHOVASCULAR INVASION IDENTIFIED
- SURGICAL MARGINS, FREE OF MALIGNANCY
- MULTIFOCI OF UROTHELIAL CARCINOMA IN-SITU IDENTIFIED
- CHRONIC CYSTITIS

Per TSS, Aggressive = 0%

PROSTATE:

- RIGHT PROSTATIC ADENOCARCINOMA, GLEASON'S SCORE 6 (3 + 3), CONFINED TO THE PROSTATE
- HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN III), MULTIFOCAL
- EXTENSIVE PROSTATIC ATROPHY WITH ACUTE AND CHRONIC INFLAMMATION
- ALL THE SURGICAL MARGINS, FREE OF MALIGNANCY

PERIVESICAL LYMPH NODES:

- NO METASTATIC CARCINOMA IDENTIFIED IN 13 LYMPH NODES EXAMINED (0/13)

LEFT PARA AORTIC LYMPH NODES (E):

- NO METASTATIC CARCINOMA IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LEFT COMMON ILIAC LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN 15 LYMPH NODES EXAMINED (0/15)

RIGHT PARA CAVAL LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT COMMON ILIAC LYMPH NODES (H):

- NO METASTATIC CARCINOMA IDENTIFIED IN 24 LYMPH NODES EXAMINED (0/24)

ICD-3

Carcinoma, urothelial NOS 8120/3

Site: Bladder NOS C67.9

JW 3/26/14

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

RIGHT LYMPH NODE OF CLOQUET (I):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN 38 LYMPH NODES EXAMINED (0/38)

LEFT LYMPH NODE OF CLOQUET (L):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (N):

- METASTATIC CARCINOMA IDENTIFIED ONE OF 42 LYMPH NODES EXAMINED (1/42)

RIGHT PRE SCIATIC LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

PRE SACRAL LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

LEFT PRE SCIATIC LYMPH NODES (Q):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT PROXIMAL URETER (R):

- BENIGN URETER
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT PROXIMAL URETER (S):

- BENIGN URETER
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

TOTAL LYMPH NODES:

- METASTATIC CARCINOMA IDENTIFIED ONE OF 170 LYMPH NODES EXAMINED (1/170)

PATHOLOGY AJCC STAGE (5TH EDITION):

BLADDER: pTis, T3aN1MX

PROSTATE: pT2aN1MX

Electronically signed by

Verified:

COMMENT:

The case was discussed with Dr. _____ on _____
Immunohistochemical stains for synaptophysin, chromogranin and pancytokeratin on D9 show the neoplastic cell in the bladder are positive for pancytokeratin and vimentin, and negative for synaptophysin and chromogranin, which support the diagnosis of urothelial carcinoma with sarcomatoid features. Immunostains for CK 903 and racemase on 19 and D22 support the diagnoses of prostatic adenocarcinoma.

SPECIMEN SOURCE:

A: "Right distal ureter"

B: "Left distal ureter"

C: "Apical urethral margin-f/s"

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

D: "Bladder, prostate"
E: "Left para aortic LN"
F: "Left common iliac LN"
G: "Right para caval LN"
H: "Right common iliac LN"
I: "Right LN of Cloquet"
J: "Right external iliac LN"
K: "Right obturator hypogastric LN"
L: "Left LN of Cloquet"
M: "Left external iliac LN"
N: "Left obturator hypogastric LN"
O: "Right pre sciatic LN"
P: "Pre sacral LN"
Q: "Left pre sciatic LN"
R: "Right proximal ureter"
S: "Left proximal ureter"

CLINICAL INFORMATION:

Pre-op Dx: Bladder cancer

Post-op Dx: Same as pre-op

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter". It consists of a segment of soft tubular gray tissue measuring 0.2 cm in length x 0.3 cm in diameter. The specimen is entirely submitted for frozen section in AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter". It consists of a segment of soft tubular gray tissue measuring 0.2 cm in length x 0.4 cm in diameter. The specimen is entirely submitted for frozen section in BFS.

C: The specimen is received fresh from the O.R. and labeled "Apical urethral margin-f/s". It consists of a piece of soft pink tissue measuring 1.5 x 0.3 x 0.2 cm. The specimen is entirely submitted by for frozen section diagnosis in CFS.

D: The specimen is received fresh from the O.R. and labeled "Bladder, prostate". The specimen overall measures 32 x 16.5 x 5.5 cm and is partially covered in a shiny, fatty, yellow-pink peritoneum measures 26.5 x 15.5 x less than 0.1 cm. The specimen consists of a bladder (15 x 9 x 5.5 cm) and attached prostate (5 x 4.2 x 3.3 cm). The right attached seminal vesicle measures 3.7 x 1.8 x 0.6 cm and the left attached seminal vesicle measures 3.3 x 1.5 x 0.8 cm. The surgical margin of the entire specimen is inked black, with the right side inked with superimposed red. The specimen is opened along the anterior urethra revealing a prostatic urethra measuring 3 cm in length x 3 cm in circumference. The verumontanum measures 1.3 x 0.3 x 0.2 cm. The urethral mucosa is pink-tan, smooth, and does not appear to be excavated. The bladder is almost entirely filled by huge, necrotic, bloody, friable, soft, exophytic mass which measures 14.5 x 8 x 5 cm. The mass appears to arise from the left lateral wall. Upon sectioning through the mass, the cut surfaces are coagulative, solid, soft and ranges in color from red to yellowish in a marbled pattern. Upon sectioning through the mass's relationship to the left lateral wall, it appears to arise from the solid, firm, light tan mass at the base and to extend into the bladder wall but not involve the underlying perivesical fat. The tumor appears to be 1 cm from the inked black margin. Bilateral attached ureters are opened. The right ureter measures 6 cm in length x 1.2 cm in circumference and the left ureter measures 7.3 cm in length x 1.1 cm in circumference. The ureteral mucosa are both grossly unremarkable. The remaining bladder mucosa is gray, congested, and grossly unremarkable elsewhere, except for the trigone where there is a firm nodularity. The specimen is taken to the O.R. in a gross consultation. The urothelium is fixed in B5 fixative for an hour and the specimen is subsequently entirely fixed in formalin. The prostate is serially sectioned from distal to proximal, revealing smooth, solid, grossly unremarkable,

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

light yellow cut surfaces. No gross tumors are noted in the prostate. No perivesical lymph nodes are palpated. Representative sections are submitted in 24 cassettes.

E: The specimen is received in formalin and labeled "Left para aortic LN". It consists of fibrofatty and lymphoid tissue measuring in aggregate 2.5 x 2.3 x 0.8 cm. Entirely submitted in three cassettes.

F: The specimen is received in formalin and labeled "Left common iliac LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 3.5 x 2.5 x 0.4 cm. Entirely submitted in three cassettes.

G: The specimen is received in formalin and labeled "Right para caval LN". It consists of fatty and lymphoid tissue measuring in aggregate 4.5 x 2.5 x 0.5 cm. Entirely submitted in two cassettes.

H: The specimen is received in formalin and labeled "Right common iliac LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 5.5 x 3.5 x 1 cm. Entirely submitted in five cassettes.

I: The specimen is received in formalin and labeled "Right LN of Cloquet". It consists of a lymph node measuring 2 x 1.8 x 0.7 cm. Serially sectioned and entirely submitted in two cassettes.

J: The specimen is received in formalin and labeled "Right external iliac LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 5 x 2.5 x 1 cm. Entirely submitted in three cassettes.

K: The specimen is received in formalin and labeled "Right obturator hypogastric LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 7 x 5 x 1.5 cm. Entirely submitted in seven cassettes.

L: The specimen is received in formalin and labeled "Left LN of Cloquet". It consists of a single lymph node measuring 1.4 x 0.9 x 0.9 cm, with a small amount of attached fat. Serially sectioned and entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "Left external iliac LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 4.2 x 2 x 0.5 cm. Entirely submitted in two cassettes.

N: The specimen is received in formalin and labeled "Left obturator hypogastric LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 7.2 x 4 x 0.8 cm. Entirely submitted in seven cassettes.

O: The specimen is received in formalin and labeled "Right pre sciatic LN". It consists of multiple fragments of fatty tissue measuring in aggregate 2 x 2 x 0.3 cm. Entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Pre sacral LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 4 x 2 x 0.5 cm. Entirely submitted in two cassettes.

Q: The specimen is received in formalin and labeled "Left pre sciatic LN". It consists of multiple fragments of fatty and lymphoid tissue measuring in aggregate 3.5 x 2 x 0.3 cm. Entirely submitted in one cassette.

R: The specimen is received in formalin and labeled "Right proximal ureter". It consists of a segment of gray-purple tubule measuring 0.3 cm in length x 0.3 cm in diameter. Serially sectioned and entirely submitted in one cassette. There are staples evenly spaced across it.

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

S: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a segment of pink-gray tubule measuring 0.3 cm in length x 0.4 cm in diameter. The specimen is stapled evenly across. Serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, apical urethral margin
D1: posterior wall of bladder
D2: dome of bladder
D3: right lateral wall of bladder
D4, 5: anterior wall of bladder
D6: right ureterovesical junction, plus representative sections through ureter
D7: left ureterovesical junction, plus representative sections through ureter
D8: trigone
D9-12: representative sections through tumor in relationship to the left lateral wall
D13: relationship of tumor to closest inked margin
D14, 15: representative sections through the hemorrhagic bladder mass
D16: right distal prostate
D17: left distal prostate
D18: right mid prostate
D19: left posterior mid prostate
D20: left anterior mid prostate
D21: right posterior proximal prostate
D22: right anterior proximal prostate
D23: left posterior proximal prostate
D24: left anterior proximal prostate
E1: left para aortic lymph nodes; one lymph node, bisected
E2: two lymph nodes, one inked black, both bisected
E3: remaining tissue
F1, 2: left common iliac lymph nodes; lymphoid tissue
F3: remaining tissue
G1: right para caval lymph nodes; one lymph node, bisected
G2: remaining tissue
H1, 2: right common iliac lymph nodes; each contain one lymph node, bisected
H3: two lymph nodes, bisected, one inked black
H4: remaining lymphoid tissue
H5: remaining tissue
I1, 2: right lymph node of Cloquet; one lymph node, serially sectioned
J1: right external iliac lymph nodes; one lymph node, bisected
J2: remaining lymphoid tissue
J3: remaining tissue
K1: right obturator hypogastric lymph nodes; one lymph node, bisected
K2-4: remaining lymphoid tissue
K5-7: remaining tissue
L1: left lymph node of Cloquet; one lymph node, serially sectioned
M1: left external iliac lymph nodes; one lymph node, bisected
M2: remaining tissue
N1, 2: left obturator hypogastric lymph nodes; each contain one half of one lymph node, bisected
N3: one lymph node, bisected
N4-6: remaining lymphoid tissue
N7: remaining tissue
O: right pre sciatic lymph nodes
P1: pre sacral lymph nodes; lymphoid tissue
P2: remaining tissue
Q: left pre sciatic lymph nodes

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Collected: [redacted]

Ordered by: [redacted]

Location: [redacted]

R: right proximal ureter
S: left proximal ureter

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter
- benign

BFS: Left distal ureter
- benign

CFS: Apical urethral margin
- benign

INTRAOPERATIVE GROSS CONSULTATION

Bladder, prostate (D):
- tumor identified

MICROSCOPIC EXAMINATION:

A-S: See final microscopic diagnosis.

Source: NCI Genomic Data Commons file ce331623-e273-4f13-a24f-169585da1500 (TCGA-XF-AAN7.B680364D-6FEC-45A5-95FC-1055E37DFCE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).